Somatic mutation profile of tumor specimen MP2PRT-PATWYH-TMP1-A (aliquot MP2PRT-PATWYH-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATWYH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (833 days).
Specimen MP2PRT-PATWYH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1291b75f-025f-4f11-8c1d-f6b4437bf57e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATWYH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATWYH-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c2d44d0-88c0-4e53-9ef7-194195cc891d

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 6, Silent 4, In Frame Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 78/276 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- DOCK1 | c.4562C>T p.P1521L | Missense Mutation (SNP) | VAF 99/462 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs369947359; called by muse, mutect2, varscan2
- MAP2K2 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 102/377 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs770521279; called by muse, mutect2
- SLC6A1 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 81/266 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs536009666; called by muse, varscan2
- ZNF215 | c.1454C>T p.T485M | Missense Mutation (SNP) | VAF 85/305 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs545734774, COSV99549948; called by muse, mutect2, varscan2
- IGKV1OR2-108 | c.352_353insGG | In Frame Ins (INS) | VAF 111/131 reads (85%) | called by mutect2, pindel*, varscan2
- MMP9 | c.250_262delinsCTCG p.G84_S88delinsLG | In Frame Del (DEL) | VAF 44/369 reads (12%) | called by pindel, varscan2*
- VCL | c.2127G>C p.M709I | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- ARFGEF3 | c.864C>T p.S288= | Silent (SNP) | VAF 153/544 reads (28%) | called by muse, mutect2, varscan2
- NOL4 | c.1308G>A p.K436= | Silent (SNP) | VAF 91/402 reads (23%) | catalogued as COSV52364350; called by muse, mutect2, varscan2
- PCDHA12 | c.1722A>G p.G574= | Silent (SNP) | VAF 201/764 reads (26%) | catalogued as rs1350324855; called by muse, mutect2, varscan2
- PCDHGA1 | c.70T>C p.L24= | Silent (SNP) | VAF 45/476 reads (9%) | called by muse, mutect2
